Somatic mutation profile of tumor specimen ALCH-B34S-TTP1-A (aliquot ALCH-B34S-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B34S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.4 years (26,081 days).
Specimen ALCH-B34S-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9599337b-6290-4498-b36c-7ede38ed47fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34S-NB1-A (Blood Derived Normal), aliquot ALCH-B34S-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6de1c70d-33a7-4625-a419-4931c66fb670

The open-access MAF lists 369 somatic variants for this specimen: 247 protein-altering or splice-affecting, 75 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 75, Intron 22, Nonsense Mutation 18, 5'UTR 8, RNA 6, 3'Flank 5, Frame Shift Del 5, 5'Flank 3, Splice Site 3, 3'UTR 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 36/358 reads (10%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 27/229 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACCS | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.125); catalogued as COSV99773051; called by muse, mutect2, varscan2
- AHI1 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV55630829; called by muse, mutect2
- AMER1 | c.2452G>T p.G818W | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57657745; called by muse, mutect2, varscan2
- APOB | c.4076C>A p.S1359Y | Missense Mutation (SNP) | VAF 24/484 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51947539; called by muse, mutect2
- ATP2B3 | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 31/454 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs782166942, COSV99685688; called by muse, mutect2
- BAP1 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs759448397, COSV56233567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL11A | c.939G>T p.Q313H (on ENST00000335712 / NM_001365609.1; = p.Q347H on NM_018014.4) | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.347); catalogued as COSV59629462; called by muse, mutect2
- BEND5 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 100/801 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65717429, COSV65718623; called by muse, mutect2, varscan2
- BEX5 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 26/651 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as rs782199206; called by muse, mutect2
- CCM2L | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230105521, COSV99395193; called by muse, mutect2, varscan2
- CDH18 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 42/756 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868527442, COSV56907663, COSV56951940; called by muse, mutect2
- CEP295NL | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs1405912676; called by muse, mutect2
- CFAP47 | c.2167G>T p.G723* | Nonsense Mutation (SNP) | VAF 21/533 reads (4%) | catalogued as COSV52888593; called by muse, mutect2
- CSMD3 | c.7073C>T p.A2358V (on ENST00000297405 / NM_001363185.1; = p.A2254V on NM_052900.3) | Missense Mutation (SNP) | VAF 38/932 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.074); catalogued as COSV52091847; called by muse, mutect2
- DFFA | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761102520; called by muse, mutect2
- DLG1 | c.1840C>A p.H614N | Missense Mutation (SNP) | VAF 77/715 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV100015964; called by muse, mutect2, varscan2
- DLG2 | c.313A>T p.N105Y | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54629580; called by muse, mutect2
- FBXL2 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 32/586 reads (5%) | catalogued as rs1054565676; called by muse, mutect2
- FGFR1 | c.1454G>A p.G485E (on ENST00000447712 / NM_023110.3; = p.G483E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58329117, COSV58346851; called by muse, mutect2, varscan2
- FGFR1 | c.1453G>A p.G485R (on ENST00000447712 / NM_023110.3; = p.G483R on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM157944; called by muse, mutect2
- FYB1 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 80/644 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV60953770; called by muse, mutect2, varscan2
- ICA1 | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 62/426 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs1472021531; called by muse, mutect2, varscan2
- KIAA1191 | c.86G>C p.R29P | Missense Mutation (SNP) | VAF 19/397 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53799605; called by muse, mutect2
- KRTAP5-3 | c.109G>C p.V37L | Missense Mutation (SNP) | VAF 48/406 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.866); catalogued as COSV68790724; called by muse, mutect2, varscan2
- LAMA2 | c.2338A>T p.T780S | Missense Mutation (SNP) | VAF 47/766 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101370727; called by muse, mutect2
- MDM1 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 32/283 reads (11%) | catalogued as rs200960850; called by muse, mutect2, varscan2
- MOCS1 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 103/648 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1453620448, COSV57935675; called by muse, mutect2, varscan2
- MROH2A | c.2808C>G p.S936R | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1443990991; called by muse, mutect2
- MUC16 | c.4862G>A p.G1621D | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs1468098641, COSV67482155; called by muse, mutect2
- NBAS | c.2924A>T p.H975L | Missense Mutation (SNP) | VAF 32/507 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs551755014, COSV99872188; called by muse, mutect2
- NF1 | c.7102G>T p.E2368* (on ENST00000358273 / NM_001042492.3; = p.E2347* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 74/723 reads (10%) | catalogued as COSV62204812; called by muse, mutect2, varscan2
- NLRP11 | c.2870G>A p.G957D | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100789652; called by muse, mutect2
- NT5C1B | c.1052C>A p.P351Q (on ENST00000359846 / NM_001199086.2; = p.P291Q on NM_033253.4) | Missense Mutation (SNP) | VAF 64/770 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58398940; called by muse, mutect2
- OR10K2 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 21/679 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV59221871; called by muse, mutect2
- OR14I1 | c.460del p.A154Qfs*18 | Frame Shift Del (DEL) | VAF 41/221 reads (19%) | catalogued as COSV100700492, COSV61200709; called by mutect2, pindel, varscan2
- OR6P1 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 23/536 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58108786; called by muse, mutect2
- PAK5 | c.1945C>A p.L649I | Missense Mutation (SNP) | VAF 43/418 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV62040238, COSV62041468; called by muse, mutect2, varscan2
- PCDHB12 | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 44/808 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.685); catalogued as rs782555743; called by muse, mutect2
- PCDHB16 | c.145G>T p.G49* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV53363989, COSV53367734; called by muse, mutect2, varscan2
- PLXNB2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as rs776198723; called by muse, mutect2, varscan2
- PPARGC1A | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.321); catalogued as COSV53534419; called by muse, mutect2, varscan2
- PSMD3 | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 102/533 reads (19%) | catalogued as COSV52858989; called by muse, mutect2, varscan2
- RELN | c.2141G>T p.S714I | Missense Mutation (SNP) | VAF 38/1390 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV59022013; called by muse, mutect2
- RXFP3 | c.951C>A p.S317R | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV57503848; called by muse, mutect2, varscan2
- SAMD14 | c.1181G>A p.R394H (on ENST00000330175 / NM_001257359.2; = p.R422H on NM_174920.4) | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs761903658; called by muse, mutect2, varscan2
- SHANK3 | c.3610G>A p.V1204I | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs1339032405, COSV53189742; called by muse, mutect2
- STAC | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 113/650 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as COSV56209466; called by muse, mutect2, varscan2
- TMEM235 | c.129C>G p.S43R | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1349075184, COSV66577654; called by muse, mutect2
- TMEM255A | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100550425; called by muse, mutect2, varscan2
- TMEM86B | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 65/323 reads (20%) | catalogued as rs747507473; called by muse, mutect2, varscan2
- TRIM3 | c.2099G>C p.G700A | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61983050; called by muse, mutect2
- TRIM42 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs1002465823, COSV53883965; called by muse, mutect2
- TRIM64C | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 56/716 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.934); catalogued as rs1366814316; called by muse, mutect2
- TTN | c.63438C>A p.S21146R (on ENST00000591111; = p.S13722R on NM_003319.4) | Missense Mutation (SNP) | VAF 34/424 reads (8%) | PolyPhen possibly damaging (0.79); catalogued as COSV100588826; called by muse, mutect2
- TYW1 | c.1129G>C p.G377R | Missense Mutation (SNP) | VAF 25/392 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV62751913; called by muse, mutect2
- UNC79 | c.2354G>A p.R785K (on ENST00000393151 / NM_001346218.2; = p.R608K on NM_020818.5) | Missense Mutation (SNP) | VAF 39/633 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs759402058; called by muse, mutect2
- UQCC1 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 99/402 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62903914; called by muse, mutect2, varscan2
- VMP1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as COSV51864345, COSV99031686; called by muse, mutect2
- XK | c.1169G>A p.R390K | Missense Mutation (SNP) | VAF 23/555 reads (4%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV66120865; called by muse, mutect2
- ZIC5 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1566398749; called by muse, mutect2, varscan2
- ZNF485 | c.452A>T p.N151I | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV104422393; called by muse, mutect2
- ZNF770 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs148085641; called by muse, mutect2
- ZNF804B | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV60825791; called by muse, mutect2, varscan2
- ZSWIM4 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs770224639; called by muse, mutect2, varscan2
- ZXDA | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62387860; called by muse, mutect2
- ABCA12 | c.6737G>A p.S2246N (on ENST00000272895 / NM_173076.3; = p.S1928N on NM_015657.3) | Missense Mutation (SNP) | VAF 46/596 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ABCB7 | c.725T>A p.L242Q (on ENST00000373394 / NM_001271696.3; = p.L243Q on NM_004299.6) | Missense Mutation (SNP) | VAF 36/968 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ACAN | c.4843G>A p.G1615R | Missense Mutation (SNP) | VAF 42/616 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.307); called by muse, mutect2
- ACSM2B | c.1681A>T p.T561S | Missense Mutation (SNP) | VAF 33/413 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.006); called by muse, mutect2
- ADAM23 | c.2356A>T p.K786* | Nonsense Mutation (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2
- ADAMTS1 | c.1084T>G p.C362G | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRB3 | c.2957T>A p.L986H | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRB3 | c.3547C>A p.Q1183K | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ADGRL3 | c.301G>A p.E101K (on ENST00000506720 / NM_001322402.2; = p.E33K on NM_015236.6) | Missense Mutation (SNP) | VAF 17/439 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- AFG3L2 | c.1867G>T p.D623Y | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALOX5 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- ANGPT2 | c.869C>A p.S290* | Nonsense Mutation (SNP) | VAF 40/448 reads (9%) | called by muse, mutect2
- ARHGEF12 | c.4133G>C p.G1378A | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARID4A | c.1150A>T p.N384Y | Missense Mutation (SNP) | VAF 29/432 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATF2 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 21/363 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- ATP2B2 | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- ATRX | c.6898del p.V2300Sfs*20 | Frame Shift Del (DEL) | VAF 122/1097 reads (11%) | called by mutect2, pindel, varscan2
- AWAT2 | c.355C>A p.H119N | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- B3GNT2 | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf71 | c.1197A>T p.E399D | Missense Mutation (SNP) | VAF 15/329 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2
- C15orf39 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- C1QA | c.711C>A p.S237R | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C4orf50 | c.730C>A p.L244I (on ENST00000324058; = p.L1476I on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/319 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); called by muse, mutect2
- C5orf49 | c.116A>T p.K39I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CABIN1 | c.68G>T p.S23I | Missense Mutation (SNP) | VAF 62/809 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2
- CASP5 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 42/646 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC151 | c.899A>G p.Y300C | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); called by muse, mutect2
- CDC42BPG | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2
- CEMIP | c.3277C>T p.L1093F | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CLOCK | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 61/750 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLTCL1 | c.1861G>T p.G621C | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTNAP2 | c.620C>A p.T207K | Missense Mutation (SNP) | VAF 69/700 reads (10%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.548); called by muse, mutect2
- COL3A1 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 48/878 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CRYM | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 33/463 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CSMD1 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- CTTNBP2 | c.2276G>T p.C759F | Missense Mutation (SNP) | VAF 25/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDO | c.872T>A p.L291H (on ENST00000368924 / NM_001368172.1; = p.L232H on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- DDX42 | c.713A>T p.K238M | Missense Mutation (SNP) | VAF 61/440 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DEFB115 | c.12T>G p.D4E | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.242); called by muse, mutect2
- DHX15 | c.2200G>T p.V734L | Missense Mutation (SNP) | VAF 41/515 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2
- DMD | c.981C>A p.D327E | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, mutect2
- DNAH5 | c.7752+1G>T p.X2584_splice | Splice Site (SNP) | VAF 61/464 reads (13%) | called by muse, mutect2, varscan2
- DNAH7 | c.6633G>T p.E2211D | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.6699G>A p.M2233I | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DPYD | c.2375C>G p.A792G | Missense Mutation (SNP) | VAF 39/861 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.073); called by muse, mutect2
- DUSP9 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EEPD1 | c.902A>G p.E301G | Missense Mutation (SNP) | VAF 33/484 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, mutect2
- ESRRB | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- F8 | c.2663C>G p.T888R | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM47A | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.281); called by muse, varscan2
- FAM83B | c.2025A>T p.L675F | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2
- FAT3 | c.8935del p.Q2979Kfs*8 | Frame Shift Del (DEL) | VAF 21/195 reads (11%) | called by mutect2, varscan2
- FBN2 | c.3163G>T p.G1055W | Missense Mutation (SNP) | VAF 42/530 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FGD1 | c.2443G>T p.A815S | Missense Mutation (SNP) | VAF 34/588 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.119); called by muse, mutect2
- FLNC | c.5705C>A p.A1902E | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FSCB | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FTSJ1 | c.669C>G p.N223K | Missense Mutation (SNP) | VAF 38/529 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2
- FYN | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- FZD10 | c.1082T>A p.I361N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GABRB3 | c.23G>T p.W8L | Missense Mutation (SNP) | VAF 23/201 reads (11%) | PolyPhen benign (0); called by muse, mutect2
- GALM | c.598A>T p.T200S | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- GRIK1 | c.1870C>A p.L624I | Missense Mutation (SNP) | VAF 25/344 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.35); called by muse, mutect2
- GSTCD | c.956A>T p.Y319F (on ENST00000360505 / NM_001031720.3; = p.Y232F on NM_024751.3) | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2
- GUCY2F | c.2873T>A p.L958* | Nonsense Mutation (SNP) | VAF 29/601 reads (5%) | called by muse, mutect2
- GYS1 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- HCN4 | c.1189T>C p.Y397H | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HCRTR2 | c.1196C>A p.T399N | Missense Mutation (SNP) | VAF 50/766 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.331); called by muse, mutect2
- HTR1A | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.233); called by muse, mutect2
- HTR1E | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HUWE1 | c.11802C>A p.F3934L | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- IFI44L | c.983T>C p.I328T | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.349); called by muse, mutect2
- IL1RN | c.86G>T p.G29V (on ENST00000409930 / NM_173842.3; = p.G11V on NM_000577.5) | Missense Mutation (SNP) | VAF 52/728 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- INPP4B | c.1957C>G p.L653V | Missense Mutation (SNP) | VAF 25/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNG1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNN2 | c.397C>T p.R133W (on ENST00000264773; = p.R345W on NM_021614.4) | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KCNQ2 | c.2075C>T p.S692F (on ENST00000359125 / NM_172107.4; = p.S664F on NM_004518.6) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNT2 | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 28/584 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2
- KIAA1210 | c.2552C>A p.T851K | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- KIAA2012 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0.02); called by muse, mutect2
- KIF12 | c.781G>T p.G261C (on ENST00000640217; = p.G123C on NM_138424.1) | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.238); called by muse, mutect2
- KIF4A | c.692G>C p.S231T | Missense Mutation (SNP) | VAF 55/443 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- KLHL1 | c.1931C>A p.T644K | Missense Mutation (SNP) | VAF 38/853 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2
- KRBA1 | c.2042del p.P681Lfs*151 | Frame Shift Del (DEL) | VAF 20/133 reads (15%) | called by mutect2, pindel, varscan2
- KRBOX1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.869); called by muse, varscan2
- KRT82 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2
- LAMA4 | c.4103C>A p.T1368N (on ENST00000230538 / NM_001105206.3; = p.T1361N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMP3 | c.824G>C p.G275A | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2
- LCAT | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LDHD | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDLRAD3 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); called by muse, mutect2
- LHFPL3 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 27/504 reads (5%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.735); called by muse, mutect2
- LRRC4C | c.1017G>T p.R339S | Missense Mutation (SNP) | VAF 32/476 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2
- MAP2 | c.4531G>T p.G1511W | Missense Mutation (SNP) | VAF 28/526 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- MDGA2 | c.1124G>C p.G375A (on ENST00000399232 / NM_001113498.2; = p.G77A on NM_182830.4) | Missense Mutation (SNP) | VAF 33/762 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- MDGA2 | c.140T>A p.L47Q | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.34); called by muse, mutect2
- MLPH | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 36/404 reads (9%) | called by muse, mutect2
- MMS22L | c.744T>G p.N248K | Missense Mutation (SNP) | VAF 21/309 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2
- MRAP | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 29/677 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- MROH2B | c.4035G>T p.M1345I | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.4772A>T p.N1591I | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- MYCN | c.935G>T p.R312M | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2
- NAA15 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NCAPH2 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NFKB1 | c.687G>C p.R229S (on ENST00000394820 / NM_001382627.1; = p.R230S on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NME7 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.019); called by muse, mutect2
- NPHP4 | c.4082C>T p.T1361I | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.071); called by muse, varscan2
- NPHP4 | c.4081A>G p.T1361A | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, varscan2
- NPHP4 | c.4080G>T p.R1360S | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, varscan2
- NPY2R | c.745C>A p.H249N | Missense Mutation (SNP) | VAF 44/702 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OCSTAMP | c.1589C>A p.P530H | Missense Mutation (SNP) | VAF 97/521 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- OR2T33 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 69/485 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.589); called by muse, varscan2
- OR4N2 | c.86T>A p.V29E | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2
- OR6S1 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PAPLN | c.99C>A p.S33R | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCARE | c.1079A>G p.Q360R | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- PCDH10 | c.501C>A p.F167L | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PCDHB4 | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 42/680 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCLO | c.10793T>C p.I3598T | Missense Mutation (SNP) | VAF 44/762 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- PHACTR1 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHEX | c.1682G>A p.W561* | Nonsense Mutation (SNP) | VAF 78/1312 reads (6%) | called by muse, mutect2
- PIAS4 | c.651C>A p.N217K | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PLEKHM1 | c.1580-3C>T | Splice Region (SNP) | VAF 22/410 reads (5%) | called by muse, mutect2
- PLS3 | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- PLXNB3 | c.9C>G p.H3Q | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRDM16 | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PRKCG | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2
- PRKCQ | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 72/555 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PWWP2A | c.1149T>G p.N383K | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RANBP17 | c.3171-1G>T p.X1057_splice | Splice Site (SNP) | VAF 10/167 reads (6%) | called by muse, mutect2
- RB1CC1 | c.4141G>T p.E1381* | Nonsense Mutation (SNP) | VAF 52/361 reads (14%) | called by muse, mutect2, varscan2
- REG3G | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 26/453 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2
- RNF139 | c.1571C>A p.T524N | Missense Mutation (SNP) | VAF 17/292 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- RNF145 | c.1675G>A p.G559S (on ENST00000424310 / NM_001199383.2; = p.G587S on NM_144726.2) | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2
- RNF212B | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ROBO4 | c.2912G>T p.R971L | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- ROCK1 | c.1418A>C p.Q473P | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SCN1A | c.4916G>T p.R1639L (on ENST00000303395 / NM_001202435.3; = p.R1628L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/712 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEMA3C | c.2068C>G p.P690A | Missense Mutation (SNP) | VAF 67/1062 reads (6%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.622); called by muse, mutect2
- SERHL | n.432-1G>T | Splice Site (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- SERHL | n.432G>T | Splice Region (SNP) | VAF 12/286 reads (4%) | called by muse, mutect2
- SH3RF1 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 62/1065 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC26A11 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC7A14 | c.2087A>G p.Y696C | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC9A4 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SNAP47 | c.1123G>C p.A375P | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2
- SORD | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.323); called by muse, mutect2
- SOX2 | c.763G>T p.V255F | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.265); called by muse, mutect2
- STARD13 | c.2853G>T p.K951N (on ENST00000336934 / NM_001243476.3; = p.K833N on NM_052851.3) | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- STEAP1 | c.889C>A p.L297I | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STK39 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2
- STOX2 | c.976A>T p.N326Y | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STX8 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- TCP11X1 | c.855del p.S286Vfs*11 | Frame Shift Del (DEL) | VAF 12/140 reads (9%) | called by mutect2, varscan2
- TEX13C | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- TMEM64 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TRIM41 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 37/370 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TRIM51GP | c.237A>T p.K79N | Missense Mutation (SNP) | VAF 21/399 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2
- TRIM64C | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 72/1004 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2
- TTN | c.54379C>A p.P18127T (on ENST00000591111; = p.P10703T on NM_003319.4) | Missense Mutation (SNP) | VAF 81/940 reads (9%) | PolyPhen possibly damaging (0.755); called by muse, mutect2
- TTN | c.42153C>A p.Y14051* (on ENST00000591111; = p.Y6627* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 66/858 reads (8%) | called by muse, mutect2
- TXNDC11 | c.1453G>C p.V485L (on ENST00000356957 / NM_001303447.2; = p.V458L on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/537 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2
- UBE2NL | c.50C>A p.A17E | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ULK4P1 | n.254+8C>T | Splice Region (SNP) | VAF 36/629 reads (6%) | called by muse, mutect2
- URB2 | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USH2A | c.4640G>T p.S1547I | Missense Mutation (SNP) | VAF 65/497 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- USP42 | c.612C>G p.Y204* | Nonsense Mutation (SNP) | VAF 56/299 reads (19%) | called by muse, mutect2, varscan2
- UTRN | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 27/343 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- VCAM1 | c.1669C>A p.P557T | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.314); called by muse, mutect2
- VWA3A | c.1394T>A p.V465E | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2
- WAS | c.1321G>T p.G441* | Nonsense Mutation (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2, varscan2
- WASHC2A | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 68/1146 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.025); called by muse, mutect2
- WDR13 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR64 | c.1820C>A p.A607D | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZNF335 | c.3890C>T p.S1297L | Missense Mutation (SNP) | VAF 126/346 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ZNF335 | c.3771C>G p.I1257M | Missense Mutation (SNP) | VAF 119/397 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ZNF502 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 32/212 reads (15%) | called by muse, mutect2, varscan2
- ZNF711 | c.368G>T p.R123M | Missense Mutation (SNP) | VAF 27/428 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.5); called by muse, mutect2
- ZNF711 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 21/337 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF775 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF90 | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 43/572 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2
- ACCSL | c.54G>T p.R18= | Silent (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.2004G>A p.T668= | Silent (SNP) | VAF 18/240 reads (8%) | catalogued as rs376367684, COSV104373580; called by muse, mutect2
- ADCY6 | c.462G>T p.L154= | Silent (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- AFF2 | c.3009C>A p.T1003= | Silent (SNP) | VAF 64/800 reads (8%) | called by muse, mutect2
- ANK2 | c.3393A>T p.P1131= | Silent (SNP) | VAF 56/1013 reads (6%) | called by muse, mutect2
- BAZ1B | c.3834T>A p.A1278= | Silent (SNP) | VAF 30/516 reads (6%) | catalogued as COSV59988613; called by muse, mutect2
- BBOX1 | c.1113G>T p.V371= | Silent (SNP) | VAF 34/482 reads (7%) | called by muse, mutect2
- BICD2 | c.915C>T p.H305= | Silent (SNP) | VAF 17/277 reads (6%) | catalogued as rs373858530; called by muse, mutect2
- CCKBR | c.507C>T p.S169= | Silent (SNP) | VAF 18/209 reads (9%) | called by muse, mutect2
- CD200R1L | c.759G>T p.L253= | Silent (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
- DCTN1 | c.1929A>C p.R643= | Silent (SNP) | VAF 27/394 reads (7%) | called by muse, mutect2
- DDO | c.321A>T p.P107= | Silent (SNP) | VAF 42/452 reads (9%) | called by muse, mutect2
- DGKA | c.1495C>A p.R499= | Silent (SNP) | VAF 15/278 reads (5%) | called by muse, mutect2
- DGKB | c.1143G>T p.L381= | Silent (SNP) | VAF 11/343 reads (3%) | called by muse, mutect2
- DRD1 | c.984C>A p.P328= | Silent (SNP) | VAF 47/574 reads (8%) | called by muse, mutect2
- ERCC2 | c.192G>C p.P64= | Silent (SNP) | VAF 55/536 reads (10%) | called by muse, mutect2, varscan2
- F13A1 | c.1464A>G p.Q488= | Silent (SNP) | VAF 20/406 reads (5%) | catalogued as rs761454622; called by muse, mutect2
- FAP | c.879C>T p.F293= | Silent (SNP) | VAF 19/259 reads (7%) | called by muse, mutect2
- FCRL1 | c.694C>T p.L232= | Silent (SNP) | VAF 24/422 reads (6%) | catalogued as rs1227034832; called by muse, mutect2
- FFAR3 | c.684G>A p.A228= | Silent (SNP) | VAF 30/709 reads (4%) | catalogued as rs377408543; called by muse, mutect2
- FHL1 | c.291C>T p.D97= | Silent (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- FTHL17 | c.243C>A p.I81= | Silent (SNP) | VAF 26/323 reads (8%) | called by muse, mutect2
- GART | c.603G>C p.L201= | Silent (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- GLP2R | c.873C>T p.P291= | Silent (SNP) | VAF 24/206 reads (12%) | called by muse, mutect2, varscan2
- GPRC5C | c.738C>A p.P246= (on ENST00000652232; = p.P201= on NM_018653.4) | Silent (SNP) | VAF 30/189 reads (16%) | called by muse, mutect2, varscan2
- GPT2 | c.516C>T p.G172= | Silent (SNP) | VAF 23/308 reads (7%) | catalogued as rs752201689, COSV60839445; ClinVar: likely benign; called by muse, mutect2
- HFM1 | c.3351T>A p.S1117= | Silent (SNP) | VAF 36/269 reads (13%) | called by muse, mutect2, varscan2
- HGF | c.63G>A p.L21= | Silent (SNP) | VAF 42/894 reads (5%) | called by muse, mutect2
- HOXD4 | c.477G>T p.T159= | Silent (SNP) | VAF 32/338 reads (9%) | called by muse, mutect2
- LAMA1 | c.5304G>A p.V1768= | Silent (SNP) | VAF 39/513 reads (8%) | catalogued as rs201040898; called by muse, mutect2
- LRIG2 | c.1164C>T p.L388= | Silent (SNP) | VAF 28/472 reads (6%) | called by muse, mutect2
- MARF1 | c.2604C>T p.A868= | Silent (SNP) | VAF 19/278 reads (7%) | called by muse, mutect2
- MDN1 | c.9978G>T p.L3326= | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- MLC1 | c.222C>T p.N74= | Silent (SNP) | VAF 36/449 reads (8%) | catalogued as rs759148867; ClinVar: likely benign; called by muse, mutect2
- MRAP | c.414C>A p.T138= | Silent (SNP) | VAF 20/167 reads (12%) | called by muse, mutect2, varscan2
- MXRA5 | c.5571C>A p.T1857= | Silent (SNP) | VAF 26/472 reads (6%) | called by muse, mutect2
- MXRA5 | c.1341G>T p.T447= | Silent (SNP) | VAF 25/470 reads (5%) | called by muse, mutect2
- NCAN | c.885G>T p.L295= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- NCAN | c.3681C>A p.I1227= | Silent (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- NCKAP5 | c.945C>T p.C315= | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as COSV58469744; called by muse, mutect2
- NGFR | c.273G>T p.G91= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2
- NTRK3 | c.2373G>C p.R791= (on ENST00000360948 / NM_001012338.2; = p.R777= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/316 reads (16%) | called by muse, mutect2, varscan2
- OPCML | c.954T>A p.I318= | Silent (SNP) | VAF 34/460 reads (7%) | called by muse, mutect2
- OR51V1 | c.321C>T p.I107= | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- OR7G1 | c.303C>A p.I101= | Silent (SNP) | VAF 23/275 reads (8%) | called by muse, mutect2
- OTUD7B | c.933C>T p.V311= | Silent (SNP) | VAF 24/442 reads (5%) | catalogued as rs376315645; called by muse, mutect2
- PAGE1 | c.93G>T p.V31= | Silent (SNP) | VAF 51/550 reads (9%) | called by muse, mutect2
- PAK5 | c.1944C>A p.P648= | Silent (SNP) | VAF 44/415 reads (11%) | called by muse, mutect2, varscan2
- PARP1 | c.417G>C p.L139= | Silent (SNP) | VAF 41/552 reads (7%) | called by muse, mutect2
- PPARGC1A | c.369T>A p.A123= | Silent (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2, varscan2
- PROX1 | c.864C>A p.A288= | Silent (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- PTPRQ | c.2496A>T p.I832= (on ENST00000616559; = p.I790= on NM_001145026.2) | Silent (SNP) | VAF 18/580 reads (3%) | catalogued as rs1166823217; called by muse, mutect2
- RET | c.2262G>C p.T754= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as rs779080598; called by muse, mutect2
- RTL1 | c.2971C>A p.R991= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs769292712, COSV66016773; called by muse, mutect2, varscan2
- RTL9 | c.3774G>C p.L1258= | Silent (SNP) | VAF 37/231 reads (16%) | called by muse, mutect2, varscan2
- RXFP1 | c.75C>T p.V25= | Silent (SNP) | VAF 21/296 reads (7%) | called by muse, mutect2
- SF3B2 | c.1329G>A p.K443= | Silent (SNP) | VAF 38/403 reads (9%) | called by muse, mutect2
- SLC16A2 | c.246G>A p.T82= | Silent (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- SLC34A1 | c.801C>A p.L267= | Silent (SNP) | VAF 22/404 reads (5%) | catalogued as COSV60998210; called by muse, mutect2
- SLC7A3 | c.999C>A p.A333= | Silent (SNP) | VAF 26/301 reads (9%) | called by muse, mutect2
- SLC9A7 | c.246G>T p.T82= | Silent (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- SMPD4 | c.2454G>A p.T818= (on ENST00000409031 / NM_017951.4; = p.T789= on NM_017751.4) | Silent (SNP) | VAF 22/294 reads (7%) | catalogued as rs553723439; called by muse, mutect2
- STAB1 | c.7197C>A p.A2399= | Silent (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- STARD10 | c.342G>A p.V114= | Silent (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- TAS2R60 | c.703C>A p.R235= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as COSV60331724; called by muse, mutect2, varscan2
- THSD7B | c.1566A>G p.T522= | Silent (SNP) | VAF 34/332 reads (10%) | called by muse, mutect2
- TMEM248 | c.105G>C p.L35= | Silent (SNP) | VAF 16/278 reads (6%) | called by muse, mutect2
- TRMT9B | c.561C>T p.G187= | Silent (SNP) | VAF 15/166 reads (9%) | catalogued as rs537461004; called by muse, mutect2
- USH2A | c.1431A>G p.Q477= | Silent (SNP) | VAF 141/767 reads (18%) | called by muse, mutect2, varscan2
- USP11 | c.387C>T p.G129= (on ENST00000218348; = p.G86= on NM_001371072.1) | Silent (SNP) | VAF 39/322 reads (12%) | called by muse, mutect2, varscan2
- ZFHX4 | c.4560C>A p.T1520= | Silent (SNP) | VAF 11/243 reads (5%) | catalogued as COSV51484442; called by muse, mutect2
- ZNF275 | c.1191G>T p.R397= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- ZNF335 | c.3840C>T p.S1280= | Silent (SNP) | VAF 136/381 reads (36%) | catalogued as rs765257687; called by muse, varscan2
- ZNF335 | c.3618C>T p.I1206= | Silent (SNP) | VAF 121/422 reads (29%) | called by muse, varscan2
- ZSWIM4 | c.255G>T p.L85= | Silent (SNP) | VAF 35/221 reads (16%) | called by muse, mutect2, varscan2
- AC011525.1 | n.845G>A | RNA (SNP) | VAF 48/343 reads (14%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9962G>T | Intron (SNP) | VAF 17/408 reads (4%) | called by muse, mutect2
- ALDH4A1 | chr1:18902567 C>A | 5'Flank (SNP) | VAF 9/66 reads (14%) | catalogued as rs1399667900; called by muse, mutect2, varscan2
- AMER1 | c.-19C>A | 5'UTR (SNP) | VAF 40/420 reads (10%) | called by muse, mutect2, varscan2
- APEX2 | c.-31C>T | 5'UTR (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2
- APOL4 | c.45-193G>T | Intron (SNP) | VAF 37/388 reads (10%) | called by muse, mutect2
- ARMCX4 | c.1038+3839C>G | Intron (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- C8orf44-SGK3 | c.-481-1853G>T | Intron (SNP) | VAF 14/98 reads (14%) | called by mutect2, varscan2
- CHRM2 | c.-47+33867G>T | Intron (SNP) | VAF 18/324 reads (6%) | catalogued as COSV57764940; called by muse, mutect2
- CLEC7A | c.492+157G>C | Intron (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- COA6 | chr1:234373669 G>A | 5'Flank (SNP) | VAF 9/67 reads (13%) | catalogued as COSV64016920; called by muse, mutect2, varscan2
- CYYR1 | c.-222C>T | 5'UTR (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2
- DES | c.-46C>A | 5'UTR (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.10762-20C>T | Intron (SNP) | VAF 26/448 reads (6%) | catalogued as rs1467064052; called by muse, mutect2
- ENOX2 | c.-2C>G | 5'UTR (SNP) | VAF 26/462 reads (6%) | called by muse, mutect2
- FAM153A | c.-56-2245C>A | Intron (SNP) | VAF 57/538 reads (11%) | called by muse, mutect2, varscan2
- FAM27E5 | n.354C>A | RNA (SNP) | VAF 42/311 reads (14%) | called by muse, mutect2, varscan2
- G6PD | c.1457+28G>T | Intron (SNP) | VAF 34/187 reads (18%) | called by muse, mutect2, varscan2
- HDGFL3 | c.607-5248G>A | Intron (SNP) | VAF 26/310 reads (8%) | called by muse, mutect2
- ITK | c.1450-32T>A | Intron (SNP) | VAF 28/548 reads (5%) | called by muse, mutect2
- KIAA1755 | c.2269-62C>A | Intron (SNP) | VAF 34/134 reads (25%) | catalogued as rs1398705037; called by muse, mutect2, varscan2
- LRR1 | chr14:49598556 G>A | 5'Flank (SNP) | VAF 14/414 reads (3%) | called by muse, mutect2
- MFSD12 | chr19:3542959 C>G | 3'Flank (SNP) | VAF 20/397 reads (5%) | called by muse, mutect2
- MYCBPAP | c.-77G>A | 5'UTR (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2
- MYL3 | chr3:46833540 C>A | 3'Flank (SNP) | VAF 29/157 reads (18%) | catalogued as rs769151255; called by muse, mutect2, varscan2
- NBPF7 | n.501G>T | RNA (SNP) | VAF 64/852 reads (8%) | called by muse, mutect2
- NDRG4 | c.21+12C>A | Intron (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- OBP2B | c.277+281G>T | Intron (SNP) | VAF 43/154 reads (28%) | catalogued as COSV64402818; called by muse, mutect2, varscan2
- OGFOD2 | c.190-30C>G | Intron (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- PCIF1 | c.*244G>C | 3'UTR (SNP) | VAF 44/120 reads (37%) | called by muse, varscan2
- PTGR2 | c.-10A>T | 5'UTR (SNP) | VAF 26/318 reads (8%) | called by muse, mutect2
- RBMXL2 | c.-23G>T | 5'UTR (SNP) | VAF 12/189 reads (6%) | called by muse, mutect2
- REXO1L1P | n.19T>C | RNA (SNP) | VAF 24/624 reads (4%) | catalogued as rs1278949698; called by muse, mutect2
- RNU6-713P | chr12:40549623 C>G | 3'Flank (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
- SH3TC2 | c.*885C>T | 3'UTR (SNP) | VAF 17/327 reads (5%) | called by muse, mutect2
- SON | c.6886-760C>T | Intron (SNP) | VAF 28/526 reads (5%) | called by muse, mutect2
- SPATA31C1 | n.3593C>A | RNA (SNP) | VAF 50/636 reads (8%) | catalogued as rs1467670243; called by muse, mutect2
- TAP2 | chr6:32822247 G>A | 3'Flank (SNP) | VAF 12/364 reads (3%) | catalogued as rs753581615, COSV66500637; called by muse, mutect2
- TSC2 | c.2545+20G>T | Intron (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2, varscan2
- TSPAN32 | c.628-91C>A | Intron (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- TTN | c.34265-4513C>A | Intron (SNP) | VAF 22/930 reads (2%) | called by muse, mutect2
- TTN | c.34265-4514C>T | Intron (SNP) | VAF 22/932 reads (2%) | called by muse, mutect2
- TTN | c.34264+2908C>T | Intron (SNP) | VAF 22/440 reads (5%) | catalogued as rs1179230741, COSV59895637; called by muse, mutect2
- UBBP4 | n.883C>G | RNA (SNP) | VAF 66/591 reads (11%) | called by muse, mutect2, varscan2
- UTS2 | chr1:7846751 ins A | 3'Flank (INS) | VAF 27/232 reads (12%) | called by mutect2, pindel, varscan2
- VAPB | c.*411G>T | 3'UTR (SNP) | VAF 46/324 reads (14%) | called by muse, mutect2, varscan2
- ZNF606 | c.-52+23G>T | Intron (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
